Somatic mutation profile of tumor specimen 0DM8W3 from CCDI case PBCAFP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 14.2 years (5,189 days).
Specimen 0DM8W3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a5a250c-3f5a-449a-91bf-43be2a4f410c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM8U8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3abbdf17-65f5-4cca-8af5-4820a70407c3

The open-access MAF lists 25 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, Intron 2, Nonsense Mutation 2, 5'UTR 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QL4 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as COSV57743972; called by muse, varscan2
- CCDC57 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 58/1070 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs777008598; called by muse, mutect2
- DCAF4L2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 185/942 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs1202467100, COSV100151058, COSV60479030; called by muse, mutect2, varscan2
- MAST1 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 307/924 reads (33%) | catalogued as COSV52245965; called by muse, mutect2, varscan2
- MMUT | c.2062G>T p.E688* | Nonsense Mutation (SNP) | VAF 219/580 reads (38%) | catalogued as rs779331475, CM060348; called by muse, mutect2, varscan2
- OR10Q1 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 137/482 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1464228910, COSV57469614; called by muse, mutect2, varscan2
- UNKL | c.2003C>T p.S668L (on ENST00000389221 / NM_001372107.1; = p.S164L on NM_001276414.2) | Missense Mutation (SNP) | VAF 108/419 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs763729183; called by muse, mutect2, varscan2
- USP49 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 239/558 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs201490425, COSV51899849; called by muse, mutect2, varscan2
- DMWD | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 266/614 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- GPR52 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 52/844 reads (6%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2
- HMGCR | c.718del p.R240Efs*3 | Frame Shift Del (DEL) | VAF 371/943 reads (39%) | called by mutect2, pindel, varscan2
- NPTXR | c.1132G>A p.G378S | Missense Mutation (SNP) | VAF 306/797 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TJP3 | c.1439T>A p.I480N | Missense Mutation (SNP) | VAF 84/782 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAF7 | c.1795G>T p.V599L | Missense Mutation (SNP) | VAF 292/688 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ABCA13 | c.12856C>A p.R4286= | Silent (SNP) | VAF 359/1252 reads (29%) | catalogued as rs199968836, COSV68949263; called by muse, mutect2, varscan2
- ELN | c.459C>T p.G153= | Silent (SNP) | VAF 72/646 reads (11%) | catalogued as rs781998810; called by muse, mutect2, varscan2
- NACAD | c.945C>A p.G315= | Silent (SNP) | VAF 130/1034 reads (13%) | catalogued as rs1311094108; called by muse, mutect2, varscan2
- PCSK2 | c.1731C>T p.S577= | Silent (SNP) | VAF 103/528 reads (20%) | catalogued as rs145152141; called by muse, mutect2, varscan2
- PDGFRA | c.1659G>A p.P553= | Silent (SNP) | VAF 281/679 reads (41%) | catalogued as rs150426218, COSV57273457; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRAMEF4 | c.1318C>T p.L440= | Silent (SNP) | VAF 292/698 reads (42%) | catalogued as rs867899956; called by muse, mutect2, varscan2
- CARM1 | c.-84G>T | 5'UTR (SNP) | VAF 8/35 reads (23%) | catalogued as rs868511606; called by muse, varscan2
- DYNC1H1 | c.6619-44C>T | Intron (SNP) | VAF 135/286 reads (47%) | called by muse, mutect2, varscan2
- FBXL5 | c.1999+55dup | Intron (INS) | VAF 100/241 reads (41%) | catalogued as rs553963627; called by mutect2, varscan2
- RIIAD1 | c.*12A>C | 3'UTR (SNP) | VAF 159/762 reads (21%) | called by muse, mutect2, varscan2
- RSPO4 | c.-25C>G | 5'UTR (SNP) | VAF 49/277 reads (18%) | catalogued as rs1227157016; called by muse, mutect2, varscan2
